PECGS case C083-000056 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/a298e539-67c6-4dd2-b47b-a63cb9fc2698

Demographics
Sex at birth: female; Age at index: 51 years; Year of birth: 1971; Education level: Some High School or Less.

Diagnoses (1)
1. Cribriform carcinoma, NOS: ICD-O-3 morphology code: 8201/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 50.8 years (18,555 days); AJCC clinical stage: Stage IIIB; AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Other clinical attributes
- BMI: 23.73; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: No.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000056_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000056_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
